Somatic mutation profile of tumor specimen TCGA-CJ-4643-01A (aliquot TCGA-CJ-4643-01A-02D-1386-10) from TCGA case TCGA-CJ-4643, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 67.0 years (24,477 days).
Specimen TCGA-CJ-4643-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fda718ba-b872-49e5-a584-043d02019c98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4643-11A (Solid Tissue Normal), aliquot TCGA-CJ-4643-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bc27443-11e3-4b79-a9b5-38f928854289

The open-access MAF lists 58 somatic variants for this specimen: 45 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 29, Silent 13, Nonsense Mutation 5, Frame Shift Del 3, Splice Region 2, Frame Shift Ins 2, In Frame Ins 1, Translation Start Site 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.343C>A p.H115N | Missense Mutation (SNP) | VAF 62/202 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as CD141839, CM961423, CM982005, COSV56545369, COSV56546151, COSV56556158, COSV56571206; called by muse, mutect2, varscan2
- ACTN2 | c.1470G>T p.W490C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63972401; called by muse, mutect2, varscan2
- ADCY10 | c.1591T>C p.Y531H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.564); catalogued as COSV100897082; called by muse, varscan2
- ARHGEF1 | c.1942T>G p.L648V | Missense Mutation (SNP) | VAF 181/695 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV61526412; called by muse, mutect2, varscan2
- ARMC10 | c.154G>T p.G52W | Missense Mutation (SNP) | VAF 83/334 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV57535176; called by muse, mutect2, varscan2
- BCAN | c.1532C>G p.A511G | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.175); catalogued as COSV61255655; called by muse, mutect2, varscan2
- BRCA1 | c.4196C>G p.T1399S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs876658465, CD032728, COSV58784770; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPQ | c.152T>A p.I51N | Missense Mutation (SNP) | VAF 2/17 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1321861762; called by mutect2, varscan2
- DNAH9 | c.11252A>T p.K3751M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52335971, COSV52344037; called by muse, mutect2, varscan2
- EQTN | c.70A>G p.I24V | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV66217960; called by muse, mutect2, varscan2
- GH2 | c.456G>C p.W152C | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV60426365; called by muse, mutect2, varscan2
- HDX | c.1469G>T p.R490L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99947669; called by mutect2, varscan2
- HPS5 | c.862C>T p.Q288* (on ENST00000349215 / NM_181507.2; = p.Q174* on NM_007216.4) | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV62538738; called by mutect2, varscan2
- IRF2BPL | c.2174C>T p.T725M | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53146167; called by muse, mutect2, varscan2
- ITGA11 | c.3520C>G p.R1174G | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV59875216; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.863G>C p.S288T | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV59822639; called by muse, mutect2, varscan2
- KCND2 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 82/282 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV58570507; called by muse, mutect2, varscan2
- LRRC46 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs534847251, COSV51635031; called by muse, mutect2, varscan2
- MYLK3 | c.1262G>C p.G421A | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.112); catalogued as COSV67362695; called by muse, mutect2, varscan2
- PER2 | c.122A>G p.H41R | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV54521643, COSV54523145; called by muse, mutect2, varscan2
- PTPRS | c.4549C>T p.Q1517* | Nonsense Mutation (SNP) | VAF 128/508 reads (25%) | catalogued as rs1236009082, COSV53611177; called by muse, mutect2, varscan2
- RASGRP4 | c.1299T>A p.C433* | Nonsense Mutation (SNP) | VAF 96/298 reads (32%) | catalogued as COSV53038193; called by muse, mutect2, varscan2
- RPH3A | c.965C>T p.P322L (on ENST00000389385 / NM_001143854.2; = p.P318L on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV66990057, COSV66993075; called by mutect2, varscan2
- RPS6KC1 | c.2639A>G p.K880R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.672); catalogued as COSV65297417; called by muse, varscan2
- RUVBL1 | c.1014C>A p.I338= | Splice Region (SNP) | VAF 22/83 reads (27%) | catalogued as rs770721140, COSV59475021; called by muse, mutect2, varscan2
- TBC1D4 | c.535A>T p.K179* | Nonsense Mutation (SNP) | VAF 103/379 reads (27%) | catalogued as COSV66487797; called by muse, mutect2, varscan2
- TICAM1 | c.1179A>T p.K393N | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV50229651; called by muse, mutect2, varscan2
- TMCO3 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 73/315 reads (23%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as rs139520979, COSV60260741; called by muse, mutect2, varscan2
- TTC12 | c.513A>C p.E171D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV59096785; called by muse, mutect2, varscan2
- UNC119 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 80/292 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs775564636, COSV52023554; called by muse, mutect2, varscan2
- UQCRFS1 | c.247A>G p.I83V | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as rs762169393, COSV59184327; called by mutect2, varscan2
- USP51 | c.1731G>T p.Q577H | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72351502; called by muse, mutect2, varscan2
- UTP15 | c.1149C>A p.P383= | Splice Region (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99707615; called by muse, varscan2
- WNK3 | c.1767T>A p.Y589* | Nonsense Mutation (SNP) | VAF 28/127 reads (22%) | catalogued as COSV63612283; called by muse, mutect2, varscan2
- ABCD4 | c.769dup p.L257Pfs*22 | Frame Shift Ins (INS) | VAF 23/163 reads (14%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.1_9del p.MEI1_?3 | Translation Start Site (DEL) | VAF 3/24 reads (13%) | called by pindel, varscan2
- CFAP44 | c.2201A>G p.E734G | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- CYFIP1 | c.387+2T>C p.X129_splice | Splice Site (SNP) | VAF 84/353 reads (24%) | called by muse, mutect2, varscan2
- GPR179 | c.6504A>C p.E2168D (on ENST00000621958; = p.E2167D on NM_001004334.4) | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MED13 | c.2400del p.K800Nfs*26 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel
- MUC17 | c.9396dup p.S3133Qfs*9 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- PBRM1 | c.336_337insCAG p.L112_T113insQ | In Frame Ins (INS) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- PSMC2 | c.601_606del p.F201_V202del | In Frame Del (DEL) | VAF 28/78 reads (36%) | called by mutect2, pindel*, varscan2*
- RELCH | c.1552del p.S518Afs*4 | Frame Shift Del (DEL) | VAF 3/21 reads (14%) | called by pindel, varscan2
- SETX | c.791del p.N264Mfs*32 | Frame Shift Del (DEL) | VAF 83/420 reads (20%) | called by pindel, varscan2
- CCDC90B | c.411G>A p.L137= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99475430, COSV99475432; called by muse, mutect2, varscan2
- CNGA2 | c.1350G>A p.K450= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV104395844, COSV61703397; called by muse, mutect2
- ERBB2 | c.1794C>T p.A598= | Silent (SNP) | VAF 35/150 reads (23%) | catalogued as COSV54064303; called by muse, mutect2, varscan2
- KLHL6 | c.975C>A p.G325= | Silent (SNP) | VAF 30/166 reads (18%) | catalogued as rs747318454, COSV58064712; called by muse, varscan2
- LAIR1 | c.78G>A p.L26= | Silent (SNP) | VAF 38/148 reads (26%) | catalogued as COSV57306116; called by muse, mutect2, varscan2
- OR5T1 | c.375T>C p.F125= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100479229; called by muse, varscan2
- OTX1 | c.702C>A p.G234= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV56993750; called by muse, mutect2, varscan2
- PTCD1 | c.1191G>A p.G397= | Silent (SNP) | VAF 62/253 reads (25%) | catalogued as COSV52861178; called by muse, mutect2, varscan2
- RBAK | c.78C>T p.D26= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- SLC6A17 | c.135C>T p.G45= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as rs201199061, COSV58991515, COSV58991607; called by muse, mutect2, varscan2
- WWP2 | c.2157G>A p.E719= | Silent (SNP) | VAF 24/364 reads (7%) | catalogued as COSV100598762; called by muse, mutect2
- ZNF610 | c.253C>T p.L85= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV58343699, COSV58344595; called by muse, mutect2, varscan2
- ZSWIM3 | c.1161G>A p.A387= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as rs149497744; called by muse, mutect2, varscan2
